Gene-level copy-number profile of tumor specimen TCGA-55-8507-01A from TCGA case TCGA-55-8507, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 53.1 years (19,390 days).
Specimen TCGA-55-8507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b9165bdb-2ff7-4e45-ad54-695f870ca9f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8507-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90147ec1-29e4-4405-b511-1b415a40135f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,554; copy number 2: 27,480; copy number 3: 10,904; copy number 4: 14,838; copy number 5: 4,181; copy number 6: 233; copy number 7: 138; copy number 8: 322; copy number 9: 143; copy number 10: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8507-01A-11D-2389-01): tumor purity 0.64, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,041 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,223,933–31,108,623, 28 genes, copy number 5: AL590729.1, PTPRU, LINC01756, AL671862.1, AC092265.1, AL645944.2, AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1.
- chr1:154,259,727–156,713,174, 143 genes, copy number 9 (broad region; genes not listed).
- chr2:114,420,125–210,171,409, 1,421 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:168,249,522–168,830,599, 1 gene, copy number 5 (within-gene range 3–5): EGFEM1P.
- chr3:168,475,198–171,996,871, 70 genes, copy number 5–7 (broad region; genes not listed).
- chr3:179,653,040–180,989,774, 27 genes, copy number 6 (within-gene range 4–6): USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1, RNA5SP149, AC134503.1, GAPDHP36, RALBP1P1, LINC02053, U8, AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19.
- chr5:58,198–2,967,955, 86 genes, copy number 5 (broad region; genes not listed).
- chr5:15,500,180–16,617,058, 12 genes, copy number 5 (within-gene range 4–5): FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1.
- chr5:21,323,873–39,074,399, 244 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:44,066,624–45,098,647, 11 genes, copy number 8: RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr6:6,534,697–7,261,993, 17 genes, copy number 5: CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5.
- chr6:45,880,827–56,954,649, 167 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr6:77,460,924–77,927,028, 3 genes, copy number 6: HTR1B, RPS6P7, MEI4.
- chr8:38,510,834–47,202,897, 150 genes, copy number 5 (broad region; genes not listed).
- chr8:63,687,179–142,209,003, 1,105 genes, copy number 5–8 (broad region; genes not listed).
- chr8:142,910,559–145,066,685, 138 genes, copy number 5 (broad region; genes not listed).
- chr12:19,775,451–27,325,959, 118 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr12:28,133,249–34,219,246, 125 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:37,575,587–38,329,721, 12 genes, copy number 5: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr13:95,310,830–95,336,201, 2 genes, copy number 5: RNY3P8, RNY4P27.
- chr14:83,805,496–97,217,778, 240 genes, copy number 5 (broad region; genes not listed).
- chr17:61,679,139–83,095,122, 706 genes, copy number 5 (broad region; genes not listed).
- chr19:28,683,071–30,713,538, 39 genes, copy number 7 (within-gene range 2–7): AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536.
- chr20:11,685,144–22,685,344, 176 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
